Surgical pathology report (de-identified scan), TCGA case TCGA-IB-A5SQ, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-A5SQ-01A (Primary Tumor).

[page 1 of 3]
Note: If you do not see "END OF PRINTED REPORT" at the bottom of the report **YOU DO NOT HAVE THE ENTIRE REPORT**. Please try printing the report.

CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected

Time Reported

Order Number

Status

Final

Ordering Provider

Relevant
Information
Location

Report Patient
Demographics
(for verification
purposes)

Name

Date of Birth

Sex: F

ICD-0-3

Adenocarcinoma, duct NOS
8500/3

Site: Head of pancreas
C25.0

QW 4/2/13

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist

Specimen Description

- A. Biopsy lesion L. liver at
- B. Gallbladder at
- C. Proximal bile duct margin at
- D. Pancreatic margin at
- E. Superior mesenteric lymph node at
- F. Whipple's specimen at

Clinical Information
Pancreatic mass

Diagnosis

- A. Liver, (Left), Biopsy:
Benign sclerotic lesion; consistent with sclerotic hemangioma
- B. Gallbladder, Cholecystectomy:
Unremarkable gallbladder with no evidence of malignancy
- C. (Proximal Bile Duct Margin), Biopsy:
Benign bile duct tissue
- D. Pancreas, (Margin), Biopsy:
Benign pancreatic tissue
- E. Lymph Node, (Superior Mesenteric), Excision:
One benign lymph node (0/1)

[page 2 of 3]
- F. Duodenum and Head of Pancreas, Whipple Resection:
Moderately differentiated adenocarcinoma of the pancreas
measuring 2.5 cm (see synoptic report for details)

Electronically signed by:
\\

Synoptic Report
F: Pancreas (Exocrine), Microscopic

HISTOLOGIC TYPE:
Ductal adenocarcinoma
HISTOLOGIC GRADE:
G2: Moderately differentiated
MICROSCOPIC TUMOR EXTENSION:
Tumor invades ampulla of Vater or sphincter of Oddi
Tumor invades duodenal wall
MARGINS:
Margins uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 3.0 mm
Specified margin: pancreatic
TREATMENT EFFECT (applicable to carcinomas treated with neoadjuvant therapy):
Not known
LYMPH-VASCULAR INVASION:
Present
PERINEURAL INVASION:
Present
PRIMARY TUMOR (pT):
pT2: Tumor limited to the pancreas, more than 2 cm in greatest dimension
REGIONAL LYMPH NODES (pN):
pN0: No regional lymph node metastasis
Number examined: 9
Number involved: 0
CLINICAL HISTORY:
Not specified
COMMENT(S):
Lymph node count includes the superior mesenteric lymph node (submitted separately as "E").

Gross Description
Received are specimens A t ~ All requisitions and specimen containers are labelled
with the patient's name, . The cassettes and AP identifiers are labelled with
the Surgical Number .

A. Specimen is received fresh for frozen section labelled as "biopsy lesion left liver".

0.7 x 0.6 x 0.2 cm piece of white to yellow tissue. All frozen.

B. Specimen is received fresh for frozen section labelled as "gallbladder" and consists
of a cholecystectomy specimen measuring 9.0 x 4.8 x 2.5 cm. The serosal surface is
unremarkable.

On opening, the gallbladder contains thick green bile but no stones. The mucosal surface
green and velvety. Representative sections are submitted in B1.

C. Specimen is received fresh for frozen section labelled as "proximal bile duct margin".

0.6 x 0.3 x 0.1 cm strip tan tissue. Totally frozen.

[page 3 of 3]
D. Specimen is received fresh for frozen section labelled as "pancreatic margin".

0.8 x 0.4 x 0.2 cm tan fragment. Totally frozen.

E. Specimen is received fresh labelled as "mesenteric lymph node" and consists of a firm tan lymph node covered by fat which measures 1.0 x 0.8 x 0.5 cm, submitted in toto in one cassette.

F. Specimen is received fresh labelled as "whipple's specimen" and consist of a resection of the distal stomach, proximal duodenum and head of pancreas. The distal gastric portion measures 2.0 cm with a circumference of 3.0 cm. It is unremarkable. The ampulla is identified which has somewhat prominent circumferential thickening. The proximal small bowel measures 18.0 cm in length with a uniform circumference of 5.0 cm. The head of pancreas section measures 6.0 x 4.0 x 2.0 cm. The resection margin is inked with blue ink. On sectioning, just deep to the ampulla is a firm poorly defined white yellow mass measuring 2.0 x 2.5 x 2.3 cm. It is closely opposed to the deep pancreatic margin but is not seen to extend beyond the pancreas. The surrounding pancreas is otherwise unremarkable.

F1 - proximal margin
F2 - distal margin
F3 - pancreatic margin
F4 - normal stomach
F5 - normal small bowel
F6-9 - pancreatic tumor
F10 - normal pancreas
F11, 12, 13 - potential lymph nodes

Frozen Section Diagnosis

A. Biopsy Lesion Left Liver:

- Benign sclerotic nodule, probable old hemangioma.
Conf # 54

C. Proximal Bile Duct Margin:

- Benign bile duct tissue.
Conf # 57

D. Pancreatic Margin:

- Benign cauterized pancreatic tissue.
Conf # 58

Reported by:

Accession
Number
Encounter
Number
Patient Location

- END OF PRINTED REPORT -

Primary Site Discrepancy		
HPA Discrepancy		
Primary Malignancy History		
Final Synchronous Primary		

Source: NCI Genomic Data Commons file 0c40d0c5-b72b-48f9-8fa5-2107e9da9265 (TCGA-IB-A5SQ.AC5FDD0E-5B64-45E4-8A37-A546BE584DEB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).